Somatic mutation profile of tumor specimen TCGA-19-5958-01A (aliquot TCGA-19-5958-01A-11D-1696-08) from TCGA case TCGA-19-5958, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.0 years (20,466 days).
Specimen TCGA-19-5958-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6ed72da-bc19-490a-8795-a73d256b564a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5958-10A (Blood Derived Normal), aliquot TCGA-19-5958-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee83bb3f-daf1-4a97-8e85-3987848ed0a1

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1137A>T p.K379N (on ENST00000521381 / NM_181523.3; = p.K109N on NM_181504.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57132536; called by muse, mutect2
- ABCB1 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378191421, COSV55956269; called by muse, mutect2, varscan2
- AMY2A | c.806C>G p.T269R | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101340655; called by mutect2, varscan2
- CACNA1D | c.1987A>G p.I663V (on ENST00000350061 / NM_001128840.3; = p.I683V on NM_000720.4) | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV55456958; called by muse, mutect2, varscan2
- CACNA1H | c.3679G>A p.D1227N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs376491138; called by muse, mutect2, varscan2
- CNGB1 | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV51904030; called by muse, mutect2, varscan2
- CORO7 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765337019, COSV52033641; called by muse, mutect2, varscan2
- DNAH6 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 36/76 reads (47%) | catalogued as rs143013494, COSV52865083; called by muse, mutect2, varscan2
- DNAH9 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV52363552; called by muse, mutect2, varscan2
- FRAS1 | c.1687C>A p.Q563K | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.101); catalogued as COSV53643441; called by muse, mutect2, varscan2
- HCN1 | c.1477T>A p.F493I | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV57525430; called by muse, mutect2, varscan2
- ITIH6 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775332002, COSV54488908; called by muse, mutect2, varscan2
- MAP3K19 | c.3586C>T p.P1196S | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1312783726, COSV59640795; called by muse, mutect2, varscan2
- MSH5 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV65210582, COSV65211942; called by muse, mutect2, varscan2
- MX2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs770483469, COSV58097104; called by muse, mutect2, varscan2
- MYH4 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs769526708, COSV55122774, COSV99701250; called by muse, mutect2, varscan2
- NFATC4 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as rs1352210330, COSV51599932; called by muse, mutect2
- NKD1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs753083072, COSV51692842; called by muse, mutect2, varscan2
- OR10H1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs780602555, COSV58471996; called by muse, mutect2, varscan2
- PCDH11Y | c.326T>A p.I109N (on ENST00000400457 / NM_032973.2; = p.I98N on NM_032971.3) | Missense Mutation (SNP) | VAF 61/85 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53086092; called by muse, mutect2, varscan2
- PLK2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs866031157, COSV57106854; called by muse, mutect2, varscan2
- PRKG1 | c.1985G>A p.S662N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV64774548; called by muse, mutect2, varscan2
- PRSS16 | c.1468G>T p.G490W | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57916158; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV50253550, COSV99242265; called by muse, mutect2, varscan2
- SCN2B | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV54051427; called by muse, mutect2, varscan2
- SLC22A3 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745719495, COSV51711162; called by muse, mutect2, varscan2
- TBC1D2 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs769803981, COSV59787008; called by muse, mutect2, varscan2
- TBC1D8B | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 88/125 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV52181406; called by muse, mutect2, varscan2
- TGFBI | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59354100; called by muse, mutect2, varscan2
- TTN | c.11527A>T p.T3843S (on ENST00000591111; = p.T3797S on NM_003319.4) | Missense Mutation (SNP) | VAF 41/134 reads (31%) | catalogued as COSV60311429; called by muse, mutect2, varscan2
- DOCK2 | c.317_318del p.Y106Cfs*34 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- IGHV4-28 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ANXA6 | c.684C>T p.A228= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100637092, COSV62908210; called by muse, mutect2, varscan2
- ATP10A | c.4482T>A p.S1494= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV63520749; called by muse, mutect2, varscan2
- ERAL1 | c.120A>G p.Q40= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs1212470145, COSV54740506; called by muse, mutect2, varscan2
- ICAM4 | c.636G>A p.A212= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as rs1366322253, COSV53426980; called by muse, mutect2, varscan2
- IRS2 | c.2283G>A p.L761= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs780182912, COSV65480798; called by muse, mutect2
- LRPPRC | c.2829G>T p.V943= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV53240979; called by muse, mutect2, varscan2
- MGRN1 | c.1170G>A p.S390= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs372689801; called by muse, mutect2, varscan2
- NDST1 | c.2097C>T p.V699= | Silent (SNP) | VAF 125/359 reads (35%) | catalogued as COSV55788870; called by muse, mutect2, varscan2
- PIWIL1 | c.834T>A p.T278= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV55349655; called by muse, mutect2, varscan2
- PSG9 | c.525C>T p.D175= | Silent (SNP) | VAF 113/330 reads (34%) | catalogued as rs150952802, COSV52484598; called by muse, mutect2, varscan2
- RIC8A | c.597G>A p.T199= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs763968936, COSV57315859; called by muse, mutect2, varscan2
- SAMD12 | c.105T>A p.S35= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV59053624; called by muse, mutect2, varscan2
- ZFP69 | c.561G>A p.T187= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as rs756573974, COSV65529243; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120778 C>T | 3'Flank (SNP) | VAF 32/110 reads (29%) | catalogued as rs532765750; called by muse, mutect2, varscan2
